Surgical pathology report (de-identified scan), TCGA case TCGA-62-A470, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A470-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, upper lobe: 16.0 x 11.0 x 8.0 cm

tumor: 6.5 x 5.0 x 4.5 cm

Diagnosis:

Adenocarcinoma, predominantly acinar

Infiltration of pleura visceralis

pT2, pN0 (0/14), pMx, G2

ICD-0-3

adenocarcinoma acinar 8550/3

Site: lung, upper lobe C34.1

hw
9/24/12

Pathologist:

1

Reviewed (initials)	Date reviewed: 9/24/12	

hw
9/24/12

Source: NCI Genomic Data Commons file 1970b281-7b6b-43dc-bbdb-390a683a2f69 (TCGA-62-A470.C0136855-AF03-4065-8563-5C2B232D7070.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).